Gene-level copy-number profile of tumor specimen HTMCP-03-06-02144-01B from CGCI case HTMCP-03-06-02144, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 45.9 years (16,779 days).
Specimen HTMCP-03-06-02144-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 000fe7ba-1d70-485d-88dc-9d8eaedd3ad8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02144-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/c7912814-67ce-48eb-8f06-1898647aefb3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 198; copy number 2: 19,362; copy number 3: 17,577; copy number 4: 12,275; copy number 5: 7,499; copy number 6: 1,267; copy number 7: 117; copy number 8: 31; copy number 9: 5; copy number 10: 1; copy number 17: 1; copy number 18: 2; copy number 42: 5; copy number 101: 9; copy number 127: 13.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:60,914,407–60,964,196, 5 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr10:47,689,707–48,031,640, 9 genes (within-gene range 0–2): SHLD2P3, RN7SL453P, RHEBP2, FO681492.1, AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P.
- chr10:48,050,282–48,060,016, 1 gene: BMS1P7.
- chr11:55,662,201–55,839,738, 14 genes: OR4C6, OR4V1P, OR4P1P, AP006437.1, OR5D2P, OR5D3P, OR5D17P, OR5D13, OR5D15P, OR5D14, OR5L1, OR5D18, OR5L2, OR5D16.
- chr19:37,235,507–37,304,395, 2 genes (within-gene range 0–4): AC016590.1, LINC01535.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,314 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–2,636,620, 172 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:5,990,927–6,784,843, 29 genes, copy number 5 (within-gene range 4–5): KCNAB2, CHD5, AL031847.1, RPL22, RNF207-AS1, RNF207, ICMT, LINC00337, HES3, GPR153, ACOT7, AL031848.2, HES2, ESPN, MIR4252, AL031848.1, TNFRSF25, PLEKHG5, NOL9, RNU6-731P, AL591866.1, TAS1R1, ZBTB48, KLHL21, PHF13, THAP3, DNAJC11, LINC01672, CAMTA1-DT.
- chr1:7,915,871–12,841,357, 162 genes, copy number 5–8 (broad region; genes not listed).
- chr1:15,409,888–16,352,480, 49 genes, copy number 5: EFHD2, CTRC, CELA2A, CELA2B, CASP9, DNAJC16, SCARNA21B, AL121992.3, AGMAT, AL121992.1, CHCHD2P6, RNU7-179P, CD24P1, DDI2, RSC1A1, AL121992.2, PLEKHM2, AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82, FBLIM1, RPL12P14, UQCRHL, AL450998.1, FLJ37453, SPEN, AL034555.1, ZBTB17, AL355994.4, AL355994.1, AL355994.5, TBC1D3P6, SRARP, AL355994.3, HSPB7, CLCNKA, AL355994.2, CLCNKB, FAM131C, EPHA2, AL451042.2, AL451042.1, ARHGEF19-AS1, ARHGEF19, ANO7L1, CPLANE2, MT1XP1, FBXO42.
- chr1:18,904,280–29,181,900, 356 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:32,600,172–33,123,492, 20 genes, copy number 6 (within-gene range 4–6): ZBTB8OS, Y_RNA, RBBP4, SYNC, AC114489.1, KIAA1522, YARS1, S100PBP, FNDC5, HPCA, TMEM54, AL031602.2, RNF19B, AL031602.1, AL355864.1, AL355864.2, AL020995.1, AK2, Metazoa_SRP, AZIN2.
- chr1:34,974,356–36,402,859, 46 genes, copy number 5: AC114490.3, AC114490.1, AC114490.2, TMEM35B, ZMYM6, ZMYM1, RPL12P45, EFCAB14P1, SFPQ, Y_RNA, ZMYM4, RN7SL503P, SNORA62, RPL5P4, ZMYM4-AS1, Metazoa_SRP, KIAA0319L, AC004865.1, NCDN, TFAP2E-AS1, TFAP2E, PSMB2, C1orf216, CLSPN, AL354864.1, AGO4, AGO1, CFAP97P1, AL139286.2, AL139286.1, AGO3, AL138787.2, AL138787.1, TEKT2, ADPRS, COL8A2, TRAPPC3, MAP7D1, RN7SL131P, THRAP3, UBE2V2P4, SH3D21, EVA1B, STK40, LSM10, RNU4-27P.
- chr1:38,885,807–121,580,524, 1,572 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr1:150,293,861–175,045,648, 861 genes, copy number 5–6 (broad region; genes not listed).
- chr1:177,923,956–223,864,851, 793 genes, copy number 5 (broad region; genes not listed).
- chr1:223,951,394–236,524,508, 326 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:32,103,445–36,688,334, 77 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:36,667,717–37,753,435, 17 genes, copy number 5–6 (within-gene range 3–6): AC008957.3, AC026741.1, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P.
- chr5:40,512,333–52,080,987, 108 genes, copy number 5 (broad region; genes not listed).
- chr6:85,557,978–85,869,464, 10 genes, copy number 5 (within-gene range 4–5): AL589666.1, SYNCRIP, SNHG5, PKMP3, SNORD50B, AL355615.1, SMIM11P1, RNU4-72P, Y_RNA, AL450338.1.
- chr6:110,598,093–111,047,521, 15 genes, copy number 5: AL512430.4, CDK19, AL512430.1, AL512430.2, AL603914.1, RNU6-957P, SNORA40C, RNU6-1115P, CNN2P9, Z84480.1, AMD1, AL357515.1, GTF3C6, RPF2, GSTM2P1.
- chr7:38,239,580–38,249,572, 1 gene, copy number 7: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 7: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr8:7,170,550–7,191,563, 2 genes, copy number 9: SNRPCP15, RPS3AP33.
- chr8:142,657,460–145,066,685, 155 genes, copy number 5 (broad region; genes not listed).
- chr9:11,618,496–28,888,955, 216 genes, copy number 6–127 (broad region; genes not listed).
- chr9:66,082,350–66,085,031, 2 genes, copy number 18: SNX18P4, AL513478.1.
- chr9:125,200,542–125,367,207, 6 genes, copy number 5: RABEPK, HSPA5, AL354710.2, GAPVD1, AL354710.1, RNU6-1020P.
- chr12:67,265,842–67,266,966, 1 gene, copy number 5: GGTA2P.
- chr14:21,962,819–22,505,167, 74 genes, copy number 7 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.
- chr15:19,878,555–96,551,517, 2,064 genes, copy number 5–7 (broad region; genes not listed).
- chr15:97,215,812–101,979,093, 124 genes, copy number 6 (broad region; genes not listed).
- chr16:1,240,379–1,242,554, 1 gene, copy number 9: TPSAB1.
- chr16:4,777,606–4,801,423, 4 genes, copy number 7 (within-gene range 3–7): SEPTIN12, AC020663.4, SMIM22, AC020663.2.
- chr16:48,244,300–48,363,122, 1 gene, copy number 5 (within-gene range 3–5): LONP2.
- chr20:47,501,887–47,656,877, 2 genes, copy number 5 (within-gene range 3–5): NCOA3, AL034418.1.
- chr20:53,608,354–53,668,758, 2 genes, copy number 5 (within-gene range 3–5): AC005808.1, RNU7-14P.
- chr21:7,744,962–8,680,934, 28 genes, copy number 8–17: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2.
- chr22:18,773,665–18,843,399, 2 genes, copy number 9 (within-gene range 3–21): GGT3P, AC008132.2.

Autosomal genes at a single copy (total copy number 1): 198. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
